MMRF case MMRF_2112 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8047da06-f35e-4211-b218-60cfc2cc7309

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 201 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 52.0 years (19,011 days); ISS stage: II; Days to last known disease status: 201 days; Days to last follow up: 201 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 201 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 5 days; Days to treatment end: 201 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 201.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -57 (ECOG 3): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 257 mg/dL; Immunoglobulin G 42.8 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 9.54 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 8.09 ×10⁹/L; Platelets 294 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 32 g/L; Total Protein 9.1 g/dL; Glucose 6.33 mmol/L; C-Reactive Protein 7.39 mg/dL.
- Day 43 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 2.79 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.05 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 6.76 mmol/L; Leukocytes 8 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 5.34 mmol/L.
- Day 110 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.41 mg/dL; Immunoglobulin G 8.76 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.05 mmol/L; Albumin 30 g/L; Total Protein 6.5 g/dL; Glucose 5.72 mmol/L.
- Day 190 (ECOG 5): Hemoglobin 6.7 mmol/L; Leukocytes 15.1 ×10⁹/L; Absolute Neutrophil 14.2 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 30 g/L; Total Protein 5.3 g/dL; Glucose 6.55 mmol/L.

Other clinical attributes
- Day -57: Weight: 72 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2112_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -57 days.
- Sample MMRF_2112_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -57 days.
